RC case RC-B6SK — RC-PTCL: Refractory Cancers (RC) - Peripheral T-Cell Lymphoma (PTCL)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Mature T- and NK-Cell Lymphomas; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/34346953-8831-492b-ac83-207fd7f296d2

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Year of birth: 1946; Vital status: Alive; Country of birth: United States.

Diagnoses (2)
1. Angioimmunoblastic T-cell lymphoma (the primary disease): ICD-O-3 morphology code: 9705/3; ICD-10 code: C84; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Classification of tumor: primary; Age at diagnosis: 64.7 years (23,616 days); Year of diagnosis: 2011; Method of diagnosis: Excisional Biopsy; Ann Arbor B symptoms: Yes; Prior malignancy: yes; Synchronous malignancy: No; Prior treatment: No; Ann arbor b symptoms described array: Fever / Night Sweats; Ann Arbor extranodal involvement: No; International Prognostic Index (IPI): Low Risk; Sites of involvement: Lymph Node, Axillary / Lymph Node, Iliac-Common / Lymph Node, Iliac-External / Lymph Node, Inguinal / Lymph Node, Mediastinal / Lymph Node, Para-Aortic / Spleen.
   Pathology details: Bone marrow malignant cells: Yes; Greatest tumor dimension: 18.5 cm; Timepoint category: Initial Diagnosis.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cyclophosphamide + Doxorubicin + Methotrexate + Prednisone + Rituximab + Vincristine; Initial disease status: Initial Diagnosis; Regimen or line of therapy: R-M-CHOP; Days to treatment start: 7 days; Days to treatment end: 105 days; Number of cycles: 4; Treatment outcome: Complete Response; Reason treatment ended: Course of Therapy Completed; Clinical trial indicator: Yes; Timepoint category: First Treatment; Treatment effect indicator: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Gemcitabine + Pegylated Liposomal Doxorubicin Hydrochloride + Vinorelbine; Initial disease status: Initial Diagnosis; Regimen or line of therapy: GVD; Days to treatment start: 7 days; Days to treatment end: 105 days; Number of cycles: 4; Treatment outcome: Complete Response; Reason treatment ended: Course of Therapy Completed; Clinical trial indicator: Yes; Timepoint category: First Treatment; Treatment effect indicator: Yes.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Days to treatment start: 186 days; Treatment outcome: Complete Response; Treatment effect indicator: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Treatment intent type: Adjuvant; Treatment outcome: Complete Response; Timepoint category: Postoperative.
   Recorded as not given: Organ Transplantation; adjuvant Radiation Therapy, NOS, postoperative; Stem Cell Transplantation, Allogeneic; Stem Cell Transplantation, NOS.
2. Prior malignancy of the colon (histology not recorded by GDC). Age at diagnosis: 64.0 years (23,374 days); Year of diagnosis: 2010; Days to diagnosis: -242 days.
   Treatment given: Treatment type: Surgery, NOS; Days to treatment start: -242 days; Treatment anatomic sites: Other.
   Recorded as not given: Pharmaceutical Therapy, NOS; Radiation Therapy, NOS.

Follow-up (4 entries)
- Day 0 (initial diagnosis): Karnofsky performance status: 40.
- Days to follow up: 52 days; Disease response: Partial Response.
- Day 381 (end of treatment course 1): Disease response: Tumor Free; Imaging type: PET; Imaging result: Negative.
- Day 4,140 (within 2 months after completion of first-course treatment): Disease response: Tumor Free; Imaging type: PET; Imaging result: Negative.

Molecular and laboratory tests
- Lactate Dehydrogenase 340 U/L [Blood test normal range upper: 250].

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 88 kg; Height: 173 cm; BMI: 29.4.
- Timepoint category: Prior to Diagnosis; Risk factors: Skin Rash.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker.

Family history
- Relative with cancer history: yes; Relationship type: Father; Relationship primary diagnosis: Lung Cancer.
- Relative with cancer history: yes; Relationship type: Sister; Relationship primary diagnosis: Colorectal Cancer.

Biospecimens (2 samples)
- Sample RC-B6SK-NB1-A: Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Preservation method: Frozen. An open-access masked somatic mutation file (MAF) exists for this specimen and lists no variants.
- Sample RC-B6SK-TMP1-A: Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow Components NOS; Preservation method: Frozen. An open-access masked somatic mutation file (MAF) exists for this specimen and lists no variants.
